Somatic mutation profile of tumor specimen MBCProject_1819_T2B_WES (aliquot MBCProject_1819_T2B_WES_1) from CMI case MBCProject_1819, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 45.2 years (16,515 days).
Specimen MBCProject_1819_T2B_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Axilla; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8a451a9-3d1e-420c-9c5c-6c6d930990c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1819_SALIVA (Saliva), aliquot MBCProject_1819_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78c17245-89f0-45ad-ba14-fdffc7bc5f70

The open-access MAF lists 47 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 10, Intron 3, 3'UTR 2, 5'Flank 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 21/95 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C1orf87 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); catalogued as rs772501233; called by mutect2, varscan2
- CEP70 | c.314C>G p.A105G | Missense Mutation (SNP) | VAF 9/244 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV53876087; called by muse, mutect2
- CSMD2 | c.8468C>T p.S2823F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as COSV53948476; called by muse, mutect2
- DSG2 | c.523C>G p.H175D | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs375422019, COSV55199493; called by muse, varscan2
- HECTD1 | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs773261934; called by muse, mutect2, varscan2
- KMT5B | c.1461T>A p.N487K | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV58563599; called by muse, mutect2
- RAD54B | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV60254435; called by muse, mutect2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 58/351 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2, varscan2
- TUBB8B | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1247629890; called by muse, varscan2
- UNC5D | c.2203C>G p.L735V | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV54772013; called by muse, mutect2, varscan2
- ACTB | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 34/407 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- ADAM9 | c.1444G>A p.V482I | Missense Mutation (SNP) | VAF 245/359 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CD82 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- CERS3 | c.261C>G p.F87L | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2
- CPNE5 | c.428C>G p.S143C | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- CT55 | c.131C>G p.T44R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FAT1 | c.4018A>G p.R1340G | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRMD8 | c.1145A>G p.D382G | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.071); called by muse, mutect2
- GOLT1A | c.301T>A p.F101I | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- GOSR1 | c.749A>T p.H250L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- LRP4 | c.2726C>A p.A909D | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC6 | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.077); called by muse, mutect2
- MICAL2 | c.2263G>T p.G755C | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.245); called by muse, varscan2
- MYO6 | c.2179G>T p.A727S | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- PFAS | c.1456C>G p.R486G | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SFMBT2 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2
- SNX13 | c.1195C>G p.H399D | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.009); called by muse, mutect2
- TP53 | c.731dup p.G245Rfs*19 | Frame Shift Ins (INS) | VAF 15/120 reads (13%) | called by mutect2, pindel, varscan2
- ABCG4 | c.1272C>A p.T424= | Silent (SNP) | VAF 28/116 reads (24%) | called by muse, mutect2, varscan2
- CTNND2 | c.2436G>A p.K812= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV58883365; called by muse, varscan2
- DCAF13 | c.1338A>G p.*446= | Silent (SNP) | VAF 13/138 reads (9%) | catalogued as rs763601552; called by muse, mutect2
- NKD2 | c.384C>T p.F128= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- NLRP12 | c.2710C>T p.L904= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as rs1420357536; called by muse, mutect2, varscan2
- OR4S2 | c.637C>T p.L213= | Silent (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- SCN10A | c.4588T>C p.L1530= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2
- SPATA16 | c.1467C>T p.P489= | Silent (SNP) | VAF 43/200 reads (22%) | catalogued as rs755176371; called by muse, mutect2, varscan2
- ZFC3H1 | c.417C>A p.L139= | Silent (SNP) | VAF 12/262 reads (5%) | called by muse, mutect2
- ZXDA | c.852G>A p.L284= | Silent (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- AHI1 | chr6:135497837 C>G | 5'Flank (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- AK2 | c.*1208T>C | 3'UTR (SNP) | VAF 20/263 reads (8%) | called by muse, mutect2
- C2CD6 | c.1581+2094G>C | Intron (SNP) | VAF 8/60 reads (13%) | catalogued as rs1462381977; called by muse, mutect2
- CCNQP1 | n.54C>G | RNA (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2
- IRF7 | c.719-22C>A | Intron (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- LUC7L | c.61+923A>G | Intron (SNP) | VAF 36/260 reads (14%) | called by muse, varscan2
- PSMB3 | chr17:38750080 G>A | 5'Flank (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- ZNF827 | c.*195C>T | 3'UTR (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
